Somatic mutation profile of tumor specimen MBCProject_0243_T1_WES (aliquot MBCProject_0243_T1_WES_1) from CMI case MBCProject_0243, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 30.0 years (10,945 days).
Specimen MBCProject_0243_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 282bd6fd-e4dc-4a8f-9702-f381ed499fc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0243_SALIVA (Saliva), aliquot MBCProject_0243_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/840456e1-aee9-4d94-bdb9-3d6f2f2b29ab

The open-access MAF lists 72 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 16, Intron 7, 3'UTR 3, Nonsense Mutation 3, Frame Shift Del 3, 5'UTR 2, Frame Shift Ins 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.115); catalogued as COSV55874619, COSV99702878; called by muse, mutect2, varscan2
- AP5M1 | c.338A>T p.E113V | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1013032443; called by muse, mutect2
- ARSI | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as rs544577332; called by muse, mutect2, varscan2
- BAHCC1 | c.7903G>A p.V2635M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as rs368667311; called by muse, mutect2
- CNGB1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs574295098, COSV51901177; called by muse, mutect2
- CRTAC1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1297093007, COSV54011038; called by muse, mutect2
- FPGT-TNNI3K | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs200522674; called by muse, mutect2
- GPAT4 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs377030711; called by muse, mutect2, varscan2
- HLA-F | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs753225754; called by muse, mutect2
- HYAL1 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99807822; called by muse, mutect2
- KRTAP19-1 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as rs201021436; called by muse, mutect2
- MEMO1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs775618103, COSV54451903; called by mutect2, varscan2
- NRBP2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.58); catalogued as rs1554652590, COSV59919170; called by muse, mutect2
- PATJ | c.3057C>G p.H1019Q | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV57159060; called by muse, mutect2
- PRR23A | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV67214716; called by muse, mutect2
- TP53 | c.911del p.T304Ifs*41 | Frame Shift Del (DEL) | VAF 87/283 reads (31%) | catalogued as COSV52772403, COSV53265486, COSV53758554; called by mutect2, pindel, varscan2
- UGT2B17 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as rs558443905, COSV100497173; called by muse, mutect2
- CCDC89 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.181); called by muse, mutect2
- CEP135 | c.2629C>G p.Q877E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.079); called by muse, mutect2
- CHD1 | c.3139A>C p.I1047L | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- ENKUR | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 43/295 reads (15%) | called by muse, mutect2, varscan2
- GOLGA1 | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR179 | c.4951C>G p.P1651A (on ENST00000621958; = p.P1650A on NM_001004334.4) | Missense Mutation (SNP) | VAF 19/435 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- HYAL1 | c.546G>C p.W182C | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KTN1 | c.1960T>A p.L654I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2
- LAMA3 | c.8005G>A p.G2669R (on ENST00000313654 / NM_198129.4; = p.G1060R on NM_000227.6) | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MALRD1 | c.6437G>A p.G2146E | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.198); called by muse, mutect2
- MMS22L | c.2090del p.L697Hfs*29 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel*, varscan2
- NEK3 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NSD1 | c.5824C>T p.P1942S | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.347); called by muse, mutect2
- NTNG1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- NUP205 | c.3833C>G p.A1278G | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NWD2 | c.4015T>A p.C1339S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.22889G>A p.S7630N | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- POLH | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.067); called by muse, mutect2
- RBM48 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINI1 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIRPG | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TCP10L | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM40 | c.63_64insCCCGGGAA p.D22Pfs*5 | Frame Shift Ins (INS) | VAF 28/149 reads (19%) | called by mutect2, pindel, varscan2
- ULK2 | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF446 | c.447del p.G150Vfs*7 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- BCO1 | c.393C>T p.C131= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs748475104, COSV50729668; called by muse, mutect2
- FAM122A | c.789T>C p.T263= | Silent (SNP) | VAF 62/303 reads (20%) | called by muse, mutect2, varscan2
- FASN | c.4254C>T p.D1418= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs763488231; called by muse, mutect2, varscan2
- JRKL | c.999G>A p.T333= | Silent (SNP) | VAF 29/182 reads (16%) | catalogued as rs753303916; called by muse, mutect2, varscan2
- LCOR | c.852G>T p.T284= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV63632201; called by muse, mutect2, varscan2
- PCDHA5 | c.1404G>C p.P468= | Silent (SNP) | VAF 42/328 reads (13%) | catalogued as COSV65350487; called by muse, mutect2, varscan2
- SLC22A9 | c.1219C>A p.R407= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as COSV54168620, COSV99655009; called by muse, mutect2, varscan2
- STAB2 | c.1701G>A p.K567= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs1445893297; called by muse, mutect2
- SYTL2 | c.1176T>C p.F392= | Silent (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2, varscan2
- TMTC2 | c.567A>C p.G189= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- TRPS1 | c.1101C>T p.P367= (on ENST00000220888 / NM_001330599.2; = p.P380= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/558 reads (3%) | catalogued as rs1422916590; called by muse, mutect2
- TTC5 | c.93C>T p.F31= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs140729593; called by muse, mutect2, varscan2
- UBR4 | c.4410C>G p.R1470= | Silent (SNP) | VAF 41/372 reads (11%) | called by muse, mutect2, varscan2
- WNT6 | c.321C>T p.F107= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- XIRP2 | c.489T>C p.S163= (on ENST00000628543; = p.S338= on NM_152381.6) | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- ZDHHC3 | c.648C>A p.L216= (on ENST00000424952 / NM_001135179.2; = p.L244= on NM_016598.3) | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV99943695; called by muse, mutect2, varscan2
- ACAN | c.2026+30C>T | Intron (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- CD58 | c.706+59G>C | Intron (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- CFAP45 | c.-44G>C | 5'UTR (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- DAO | c.696-11T>C | Intron (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- HGSNAT | c.1013-1640G>A | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as rs368341838; called by muse, varscan2
- JPT2 | c.*181T>C | 3'UTR (SNP) | VAF 29/324 reads (9%) | called by muse, mutect2
- KLF6 | c.*839A>C | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- LILRB2 | c.-11G>A | 5'UTR (SNP) | VAF 8/86 reads (9%) | catalogued as rs1198821031, COSV100079489; called by muse, mutect2
- MEAF6 | c.*348T>C | 3'UTR (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- OR9Q1 | c.-15+53432C>T | Intron (SNP) | VAF 34/186 reads (18%) | catalogued as rs1304769437; called by muse, mutect2, varscan2
- RET | c.338-33C>T | Intron (SNP) | VAF 16/122 reads (13%) | catalogued as rs746015752, COSV100395092; called by muse, mutect2, varscan2
- SQSTM1 | c.205+446G>C | Intron (SNP) | VAF 20/682 reads (3%) | catalogued as COSV62434794; called by muse, mutect2
- UBE2DNL | n.626C>T | RNA (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- ZNF487 | chr10:43436842 G>A | 5'Flank (SNP) | VAF 30/193 reads (16%) | catalogued as rs1202826177; called by muse, mutect2, varscan2
